Surgical pathology report (de-identified scan), TCGA case TCGA-CM-6172, project TCGA-COAD (Colon Adenocarcinoma), tissue source site MSKCC, specimen TCGA-CM-6172-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

SURGICAL PATHOLOGY REPORT

[REDACTED]

....

Clinical Diagnosis & History:

[REDACTED] with sigmoid adenocarcinoma.

Specimens Submitted:

- 1: Sigmoid colon and upper rectum; resection
- 2: Distal ring
- 3: Proximal ring

DIAGNOSIS:

- 1. Sigmoid colon and upper rectum; resection:

Tumor Type:

Adenocarcinoma

Histologic Grade:

Moderately differentiated

Tumor Location:

Sigmoid colon

Tumor Size:

Length is 2 cm

Width is 1.5 cm

Maximal thickness is 0.6 cm

Tumor Budding:

Absent

Increased Tumor Infiltrating Lymphocytes:

Absent

Precursor Lesions:

Tubular adenoma

Deepest Tumor Invasion:

Subserosal adipose tissue and/or mesenteric fat

Gross Tumor Perforation:

Not identified

Lymphovascular Invasion:

Not identified

Large Venous Invasion:

Not Identified

Perineural Invasion:

Not identified

Surgical Margins:

Free of tumor

Polyps/Mucosa Dysplasia (away from the carcinoma):

Not Identified

** Continued on next page **

[page 2 of 3]
Non-Neoplastic Bowel:

Unremarkable

Lymph Nodes:

Number with metastasis: 1

Total number examined: 17

Tumor deposits in pericorectal soft tissue:

Not Identified

Tumor Staging (AJCC 7th Edition):

pT3 (Tumor invades through the muscularis propria into pericorectal tissues)

Lymph Node Stage (AJCC 7th Edition):

N1a (Metastasis in one regional lymph node)

2. Rectum, distal ring; excision:

- Benign segment of rectum with no pathologic diagnosis.

3. Colon, proximal ring; excision:

- Benign segment of colon with no pathologic diagnosis.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Gross Description:

1. The specimen is received fresh, labeled "sigmoid and upper rectum, open end is proximal". It consists of a rectosigmoid colon that measures 19 cm in length and 5 cm in diameter. The serosal surface is pink and glistening. The radial resection margin is inked black and the specimen is opened to reveal a tumor that is located 12 cm from the proximal margin and 5.5 cm from the distal margin. The tumor measures 2 cm in length and 1.5 cm in width. Serial sectioning reveals tumor invasion to a depth of 0.6 cm, which is 2.5 cm from the closest radial margin. The remaining mucosa is grossly unremarkable. Pericolic and peri-rectal adipose tissue is thoroughly examined for lymph nodes, and all possible nodes are submitted. Representative sections are submitted. TPS is submitted. The specimen is submitted for lymph node dissection.

Summary of sections:

PM - proximal margin

DM - distal margin

RM - radial margin

T - tumor

U - uninvolved mucosa

LN - lymph nodes

BLN - bisected lymph node

** Continued on next page **

[page 3 of 3]
2. The specimen is received in formalin, labeled "Distal ring" and consists of a ring of bowel measuring 1.0 cm in length and 1.5 cm in diameter. It has a stapled line through the middle. The mucosal surface is pink tan and focally hemorrhagic and the serosal surface is pink tan and smooth. The staples are removed and the soft tissue is entirely submitted.

Summary of sections:

U - undesignated

3. The specimen is received in formalin, labeled "Proximal ring" and consists of a silver metal anastomotic pin measuring 5.5 x 2.8 x 1.5 cm. At the center of the pin, a blue plastic piece is noted. A ring of pink tan soft tissue is attached measuring 1.5 x 1.4 x 1.0 cm. The mucosal surface is pink tan and focally hemorrhagic and the serosal surface is pink tan and smooth. Several sutures are noted. The sutures are removed and the soft tissue is entirely submitted.

Summary of sections:

U - undesignated

Summary of Sections:

Part 1: Sigmoid colon and upper rectum; resection

Block	Sect.	Site	PCs
1		dm	1
6		LN	14
1		pm	1
1		rm	1
3		t	3
1		u	1

Part 2: Distal ring

Block	Sect.	Site	PCs
1		U	1

Part 3: Proximal ring

Block	Sect.	Site	PCs
1		U	1

** End of Report **

Source: NCI Genomic Data Commons file e4c38b7d-3ceb-493e-a226-772d1a593782 (TCGA-CM-6172.7F0ED6DE-0830-4ABC-A900-D1A3AB274736.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).